Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A46D, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A46D-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: PROSTATE, RADICAL PROSTATECTOMY -

- A. INVASIVE, POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 5 = 8.
- B. GLEASON PATTERN 5 ACCOUNTS FOR APPROXIMATELY 5% OF THE TOTAL TUMOR VOLUME. IN ADDITION GLEASON PATTERN 4 IS ALSO SEEN AND ACCOUNTS FOR APPROXIMATELY 25% OF THE TOTAL TUMOR VOLUME.
- C. THE TUMOR INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 5% OF THE TOTAL PROSTATE VOLUME EVALUATED.
- D. THE TUMOR MEASURES 1.5 CM IN GREATEST NODULAR DIMENSION.
- E. THE TUMOR IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
- F. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- G. ALL MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
- J. TNM STAGE: T2c N0 MX.
- K. HISTOLOGIC GRADE: G3-4 (POORLY DIFFERENTIATED/UNDIFFERENTIATED).

PART 2: PELVIC LYMPH NODES, LYMPHADENECTOMY -

SIX LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/6).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 5.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	46.0gm
TUMOR SIZE:	Maximum dimension: 1.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	6
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

ICD-O-3

CQCF: adenocarcinoma, acinar 8550/3
Path: adenocarcinoma, NOS 8140/3

Site: prostate, NOS C61.9

pw
9/27/12

[page 2 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: PROSTATE, RADICAL PROSTATECTOMY -

- A. INVASIVE, POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE $3 + 5 = 8$.
- B. GLEASON PATTERN 5 ACCOUNTS FOR APPROXIMATELY 5% OF THE TOTAL TUMOR VOLUME. IN ADDITION GLEASON PATTERN 4 IS ALSO SEEN AND ACCOUNTS FOR APPROXIMATELY 25% OF THE TOTAL TUMOR VOLUME.
- C. THE TUMOR INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 5% OF THE TOTAL PROSTATE VOLUME EVALUATED.
- D. THE TUMOR MEASURES 1.5 CM IN GREATEST NODULAR DIMENSION.
- E. THE TUMOR IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
- F. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- G. ALL MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
- J. TNM STAGE: T2c N0 MX.
- K. HISTOLOGIC GRADE: G3-4 (POORLY DIFFERENTIATED/UNDIFFERENTIATED).

PART 2: PELVIC LYMPH NODES, LYMPHADENECTOMY -

SIX LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/6).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 5.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	46.0gm
TUMOR SIZE:	Maximum dimension: 1.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	6
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file af3af54f-27bd-464d-9d53-2fbd5e789ab5 (TCGA-EJ-A46D.A0EF60EA-85C2-40AA-9162-E8C96748F94D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).